Somatic mutation profile of tumor specimen MMRF_2204_1_BM_CD138pos (aliquot MMRF_2204_1_BM_CD138pos_T1_KHS5U_L11063) from MMRF case MMRF_2204, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.6 years (30,186 days).
Specimen MMRF_2204_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c772d8b-d9cc-4811-90b5-a21d238f1338.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2204_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2204_1_PB_Whole_C2_KHS5U_L08776; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f6f4d38-38fe-4a7c-a8eb-e8cde3fe201a

The open-access MAF lists 138 somatic variants for this specimen: 53 protein-altering or splice-affecting, 22 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 39, Silent 22, Intron 12, 5'UTR 4, 3'Flank 4, Nonsense Mutation 2, Splice Region 2, RNA 2, Frame Shift Del 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA3 | c.1810-4dup | Splice Region (INS) | VAF 6/28 reads (21%) | catalogued as rs756865767; called by mutect2, pindel
- C8G | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs759586476, COSV56403921; called by muse, mutect2, varscan2
- CA5A | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs139748303; called by muse, mutect2, varscan2
- CARS1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV99542250; called by muse, mutect2, varscan2
- CCHCR1 | c.2077_2079del p.L693del | In Frame Del (DEL) | VAF 62/164 reads (38%) | catalogued as rs759345745; called by pindel, varscan2
- CCIN | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 103/171 reads (60%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373879432; called by muse, mutect2, varscan2
- GRAMD1B | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1453213746; called by muse, mutect2, varscan2
- IGHV1-24 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.488); catalogued as rs782376088; called by muse, mutect2, varscan2
- IGHV2-70D | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1456429000; called by muse, varscan2
- IGHV2-70D | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1466061529; called by muse, varscan2
- IGHV2-70D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1292545219; called by muse, varscan2
- IGLV3-9 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs745621281; called by muse, varscan2
- IGLV3-9 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs757627231; called by muse, mutect2, varscan2
- KLHL6 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.403); catalogued as rs749942087, COSV58067504; called by muse, mutect2, varscan2
- LYPD6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1219327059; called by muse, mutect2
- MASP1 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV51461710; called by muse, mutect2, varscan2
- MICU3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.024); catalogued as COSV58849276; called by muse, mutect2, varscan2
- PRICKLE2 | c.1792G>T p.G598C (on ENST00000295902; = p.G542C on NM_198859.4) | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1197909088; called by muse, mutect2, varscan2
- PRRC2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs767401649, COSV61942418; called by muse, mutect2, varscan2
- PUS7L | c.714_717del p.N238Kfs*27 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | catalogued as rs780133979; called by pindel, varscan2
- RIN2 | c.880C>T p.L294F (on ENST00000255006 / NM_001242581.1; = p.L245F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.952); catalogued as rs780718694; called by muse, mutect2, varscan2
- RYR2 | c.6850G>T p.G2284C | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1358347233, COSV63710725; called by muse, mutect2
- SAMHD1 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV53430834; called by muse, mutect2, varscan2
- SERPINB3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs111442409, COSV99379727; called by muse, mutect2, varscan2
- TGOLN2 | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 117/308 reads (38%) | catalogued as COSV56406947; called by muse, mutect2, varscan2
- VAV2 | c.2354G>A p.C785Y | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as rs1456299174; called by muse, mutect2, varscan2
- ZNF568 | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as rs971606843; called by muse, mutect2, varscan2
- AL441992.2 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2
- ARPP21 | c.860A>G p.E287G | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP290 | c.4581G>A p.M1527I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTTNBP2 | c.2373-2A>T p.X791_splice | Splice Site (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- DNAJC2 | c.1041dup p.A348Sfs*3 | Frame Shift Ins (INS) | VAF 23/201 reads (11%) | called by mutect2, pindel, varscan2
- DNM1 | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, mutect2
- EVC | c.2474T>G p.L825R | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- FAM193A | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- FUT6 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 67/238 reads (28%) | called by muse, mutect2, varscan2
- GJA8 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.577); called by muse, mutect2
- GOLM2 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HGF | c.977G>C p.C326S | Missense Mutation (SNP) | VAF 96/157 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMOX1 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IGHV1-69D | c.152A>C p.Y51S | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ISLR2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MACIR | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- NR2C2 | c.1504A>G p.S502G (on ENST00000393102; = p.S521G on NM_003298.5) | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- PPP1R12C | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PPP1R21 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP2R1A | c.810C>T p.L270= | Splice Region (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- SNAPC3 | c.401A>G p.K134R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TMEM131L | c.1025C>G p.T342R | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TMEM242 | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TSPAN32 | c.413C>A p.T138K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TXNDC5 | c.1237_1258del p.G413Yfs*6 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | called by mutect2, pindel, varscan2
- ZNF638 | c.5676T>A p.D1892E | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- BRINP3 | c.1311G>C p.A437= | Silent (SNP) | VAF 47/179 reads (26%) | catalogued as COSV66516749, COSV66537597, COSV66539665; called by muse, mutect2, varscan2
- C1orf112 | c.2008T>C p.L670= | Silent (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- CFAP58 | c.2250C>T p.L750= | Silent (SNP) | VAF 5/120 reads (4%) | called by muse, mutect2
- DEUP1 | c.876A>G p.Q292= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- DOCK1 | c.4143C>T p.A1381= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as rs771141839, COSV54737170; called by muse, mutect2, varscan2
- EZH1 | c.708C>T p.I236= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- FGR | c.405T>G p.P135= | Silent (SNP) | VAF 35/226 reads (15%) | called by muse, mutect2, varscan2
- FILIP1L | c.1510C>A p.R504= (on ENST00000354552 / NM_182909.3; = p.R264= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- HAAO | c.729A>G p.G243= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs767026824; called by muse, mutect2, varscan2
- HS1BP3 | c.342G>A p.E114= | Silent (SNP) | VAF 11/308 reads (4%) | catalogued as rs1036704243; called by muse, mutect2
- IGHV2-70D | c.354G>C p.R118= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, varscan2
- KLK15 | c.459C>T p.T153= | Silent (SNP) | VAF 76/169 reads (45%) | catalogued as rs1270808246, COSV56828489; called by muse, mutect2, varscan2
- LRP1B | c.3033C>T p.F1011= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- OR9A4 | c.210C>T p.I70= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV101516546; called by muse, mutect2, varscan2
- PIK3R3 | c.1344T>C p.L448= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- PLD5 | c.588A>G p.L196= (on ENST00000442594; = p.L134= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1044C>T p.V348= | Silent (SNP) | VAF 45/181 reads (25%) | catalogued as rs773142135; called by muse, mutect2, varscan2
- PTPRM | c.1638C>T p.T546= | Silent (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- RNF144A | c.807C>T p.L269= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs747815989, COSV57985423; called by muse, mutect2, varscan2
- STOML3 | c.837C>T p.V279= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- WASF3 | c.480C>T p.L160= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- ABHD13 | c.*2742G>A | 3'UTR (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- AMACR | c.*729C>A | 3'UTR (SNP) | VAF 125/442 reads (28%) | called by muse, mutect2, varscan2
- ARID1B | c.*730T>G | 3'UTR (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- ATMIN | c.462+19A>T | Intron (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- ATP10A | c.*8G>A | 3'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- BCL7A | chr12:122021570 C>G | 5'Flank (SNP) | VAF 38/88 reads (43%) | catalogued as COSV55848051; called by muse, mutect2, varscan2
- CADM3 | c.*1668G>A | 3'UTR (SNP) | VAF 35/310 reads (11%) | called by muse, mutect2, varscan2
- CAVIN3 | c.384+262C>T | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as rs997599307; called by muse, mutect2
- CBX3 | c.*23T>C | 3'UTR (SNP) | VAF 17/194 reads (9%) | catalogued as rs776117134, COSV100522967; called by muse, mutect2
- CCDC149 | c.*425G>A | 3'UTR (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- CDON | c.*4456G>T | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- CEP57L1 | c.745-1383G>A | Intron (SNP) | VAF 8/82 reads (10%) | catalogued as rs1329205691; called by muse, mutect2, varscan2
- CLDN5 | c.*346C>T | 3'UTR (SNP) | VAF 8/211 reads (4%) | called by muse, mutect2
- COL5A1 | c.*1647C>T | 3'UTR (SNP) | VAF 60/196 reads (31%) | catalogued as rs1020845061, COSV65672920; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+11261C>A | Intron (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2
- DNAJC16 | c.*1070T>A | 3'UTR (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- ELL2 | c.*1348T>G | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- FAM186A | chr12:50326669 A>G | 3'Flank (SNP) | VAF 22/104 reads (21%) | catalogued as rs1565876556; called by muse, mutect2, varscan2
- FBLN5 | chr14:91869948 T>A | 3'Flank (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- FERMT1 | c.*1710C>T | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- FKBP1C | c.*270T>C | 3'UTR (SNP) | VAF 149/394 reads (38%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+2847A>T | Intron (SNP) | VAF 27/86 reads (31%) | catalogued as rs1251722170; called by muse, mutect2, varscan2
- GPM6B | chrX:13771309 T>C | 3'Flank (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- HEBP2 | chr6:138403524 C>T | 5'Flank (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- IFNL1 | c.*126A>G | 3'UTR (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2
- IGLC2 | c.*105A>G | 3'UTR (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- INHBA | c.*3976A>T | 3'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- IST1 | c.892-621C>T | Intron (SNP) | VAF 90/233 reads (39%) | called by muse, mutect2, varscan2
- LHFPL2 | c.*2115C>G | 3'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- MINDY3 | c.-87C>T | 5'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- MIR1305 | n.71G>C | RNA (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- MYOF | c.4437+70A>G | Intron (SNP) | VAF 62/144 reads (43%) | called by muse, mutect2, varscan2
- NBN | c.*1490_*1491del | 3'UTR (DEL) | VAF 86/203 reads (42%) | called by pindel, varscan2
- NRP1 | c.*905G>A | 3'UTR (SNP) | VAF 20/103 reads (19%) | catalogued as rs766947380; called by muse, mutect2, varscan2
- OXTR | c.*161A>G | 3'UTR (SNP) | VAF 15/89 reads (17%) | catalogued as rs1310773914; called by muse, mutect2, varscan2
- PCNX1 | c.*5403G>T | 3'UTR (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- PDGFA | chr7:497562 C>A | 3'Flank (SNP) | VAF 7/204 reads (3%) | called by muse, mutect2
- PET117 | c.*605G>A | 3'UTR (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2
- PLXDC2 | c.-74G>A | 5'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, varscan2
- POMT1 | c.*219G>A | 3'UTR (SNP) | VAF 47/90 reads (52%) | catalogued as rs993064797; called by muse, mutect2
- PROP1 | c.-24G>A | 5'UTR (SNP) | VAF 136/496 reads (27%) | called by muse, mutect2, varscan2
- PTH2R | c.*668C>T | 3'UTR (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- RGS1 | c.*416A>T | 3'UTR (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- RNPEP | c.*179C>T | 3'UTR (SNP) | VAF 50/184 reads (27%) | catalogued as rs1158608515; called by muse, mutect2, varscan2
- RPL12 | c.*41T>G | 3'UTR (SNP) | VAF 80/501 reads (16%) | called by muse, mutect2, varscan2
- SCUBE3 | c.*1913C>A | 3'UTR (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- SERPINI1 | c.*68A>C | 3'UTR (SNP) | VAF 54/148 reads (36%) | called by muse, mutect2, varscan2
- SLC28A3 | c.*1657G>A | 3'UTR (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.*994G>A | 3'UTR (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- SNX27 | c.*3889G>A | 3'UTR (SNP) | VAF 71/133 reads (53%) | called by muse, mutect2, varscan2
- SNX29P2 | n.494G>A | RNA (SNP) | VAF 56/262 reads (21%) | called by muse, mutect2, varscan2
- SSBP2 | c.*1159C>T | 3'UTR (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- TCEA1 | c.897+9T>A | Intron (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- TMCC2 | c.*1069C>A | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- TMEM183A | c.*1446_*1447del | 3'UTR (DEL) | VAF 6/56 reads (11%) | catalogued as rs1241695825; called by pindel, varscan2
- TRPV6 | c.883-139T>G | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2
- TSLP | c.*1883G>T | 3'UTR (SNP) | VAF 37/157 reads (24%) | catalogued as rs960263109; called by muse, mutect2, varscan2
- UNK | c.491+55G>A | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- VMP1 | c.*1324C>G | 3'UTR (SNP) | VAF 59/164 reads (36%) | called by muse, mutect2, varscan2
- WTAP | c.452+983T>A | Intron (SNP) | VAF 139/339 reads (41%) | called by muse, mutect2, varscan2
- YTHDF1 | c.-206T>C | 5'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- ZNF418 | c.-81+208G>A | Intron (SNP) | VAF 36/59 reads (61%) | called by muse, mutect2, varscan2
- ZNF528 | c.*1369C>T | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
